Somatic mutation profile of tumor specimen TARGET-10-PATCZN-09A (aliquot TARGET-10-PATCZN-09A-01D) from TARGET case TARGET-10-PATCZN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,806 days).
Specimen TARGET-10-PATCZN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 035ff6b0-edb1-4069-aa88-4484c46a43a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATCZN-10A (Blood Derived Normal), aliquot TARGET-10-PATCZN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fff00eaa-7b23-49be-8002-2042a923ad3d

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 22/56 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.1556G>A p.R519H | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs368091573; called by muse, mutect2, varscan2
- COL11A2 | c.2545C>T p.R849W (on ENST00000341947 / NM_080680.3; = p.R742W on NM_080679.2) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1352413024, COSV59497712; called by muse, mutect2, varscan2
- DMBT1 | c.6679C>T p.R2227C (on ENST00000338354 / NM_001377530.1; = p.R1470C on NM_004406.3) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as rs745621942, COSV57545939; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, mutect2, varscan2
- NT5C1A | c.61A>G p.T21A | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs770933231, COSV52494785; called by muse, mutect2, varscan2
- SERPINH1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs764819709, COSV63998111; called by muse, mutect2, varscan2
- TF | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV53920891, COSV99395321; called by muse, mutect2, varscan2
- TDRD12 | c.1591C>T p.H531Y | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO1F | c.753C>T p.S251= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs201910417, COSV57800104; called by muse, mutect2, varscan2
- PAGE2B | c.186C>T p.A62= | Silent (SNP) | VAF 14/187 reads (7%) | catalogued as rs2498449; called by muse, mutect2
- SI | c.3732C>T p.D1244= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as rs200449490, COSV100013989, COSV52282786; called by muse, mutect2, varscan2
- MAST1 | c.1009+28G>T | Intron (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
